Somatic mutation profile of tumor specimen TCGA-EM-A1YB-01A (aliquot TCGA-EM-A1YB-01A-11D-A14W-08) from TCGA case TCGA-EM-A1YB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 73.5 years (26,852 days).
Specimen TCGA-EM-A1YB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ffd6379-c6b9-459e-9711-a389e34ec1c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1YB-10A (Blood Derived Normal), aliquot TCGA-EM-A1YB-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0681c75-342a-4f3b-b009-cd5036ffb902

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 20, Silent 12, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCAR3 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV53075354; called by muse, mutect2
- C9orf116 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV54093360; called by muse, mutect2, varscan2
- CASZ1 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV59736038; called by muse, mutect2, varscan2
- CCDC80 | c.1553C>A p.S518Y | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52817094; called by muse, mutect2, varscan2
- CTNND2 | c.3481C>G p.Q1161E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV58891773; called by muse, mutect2, varscan2
- DCX | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM087657, COSV57569927; called by muse, mutect2, varscan2
- DNAJC22 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV67711932; called by muse, mutect2
- FREM1 | c.1957G>T p.V653F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66524284; called by muse, mutect2, varscan2
- ID2 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs943625872, COSV52170052; called by muse, mutect2, varscan2
- IFNL1 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs753364897, COSV61317801; called by muse, mutect2, varscan2
- NAPG | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV59797183; called by muse, mutect2
- PCDHB10 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as rs782621624, COSV53379242; called by muse, mutect2, varscan2
- PPP6C | c.623G>C p.S208T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65208001; called by muse, mutect2, varscan2
- RPL9 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99787897; called by muse, mutect2, varscan2
- RPL9 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99787899; called by muse, mutect2, varscan2
- SESN3 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs1318902387, COSV53585103; called by muse, mutect2, varscan2
- SH3GL3 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.042); catalogued as COSV100197625; called by muse, mutect2, varscan2
- SNX29 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV73829745; called by muse, mutect2, varscan2
- TRIM46 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs1165284121, COSV55278453, COSV55278987; called by muse, varscan2
- VTI1A | c.427+1G>A p.X143_splice | Splice Site (SNP) | VAF 21/94 reads (22%) | catalogued as rs1287950135, COSV67580589; called by muse, mutect2, varscan2
- ZNF91 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV56085141; called by muse, mutect2, varscan2
- DPY19L4 | c.114_117del p.R39Lfs*25 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel
- PCGF2 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CASP3 | c.645C>T p.F215= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV57725170; called by muse, mutect2, varscan2
- H1-4 | c.129C>T p.L43= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs756055232, COSV56801299; called by muse, mutect2, varscan2
- MCM2 | c.1635C>T p.F545= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV54034046; called by muse, mutect2, varscan2
- MYO10 | c.3843C>T p.I1281= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV57022243; called by muse, mutect2
- NMBR | c.201C>T p.I67= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs368028844; called by muse, mutect2, varscan2
- PCGF2 | c.66G>A p.G22= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- PLXND1 | c.765C>T p.F255= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV60714159; called by muse, mutect2
- SLC16A13 | c.180C>T p.I60= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV57288133; called by muse, mutect2
- SPSB3 | c.201C>T p.G67= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV51905014; called by muse, mutect2, varscan2
- TREM1 | c.9G>A p.K3= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV55148587; called by muse, mutect2, varscan2
- TRIM10 | c.1233C>T p.F411= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs562843566, COSV64998492; called by muse, mutect2, varscan2
- ZNF710 | c.1758C>T p.L586= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV51563295; called by muse, mutect2, varscan2
